Somatic mutation profile of tumor specimen C3N-03220-02 (aliquot CPT0191020007) from CPTAC case C3N-03220, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 86.2 years (31,488 days).
Specimen C3N-03220-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 765d4055-8924-4371-a07a-94a60446e5cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03220-71 (Blood Derived Normal), aliquot CPT0191330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a50d55-a42e-4606-82d7-ffe3ced8c4dd

The open-access MAF lists 488 somatic variants for this specimen: 316 protein-altering or splice-affecting, 156 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 156, Nonsense Mutation 16, Intron 14, Splice Region 3, Splice Site 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 230/359 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 227/355 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASR | c.1579G>A p.E527K (on ENST00000490131; = p.E604K on NM_000388.4) | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs104893712, CM030375, COSV56134726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 93/272 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs762864760, COSV101037319, COSV66071389; called by muse, mutect2, varscan2
- ACSL1 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 102/315 reads (32%) | catalogued as COSV99860387; called by muse, mutect2, varscan2
- ADD2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 206/543 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as COSV100036747; called by muse, mutect2, varscan2
- ADGRD1 | c.1645A>G p.I549V | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs1484470803; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 147/397 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- ADRA1A | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 181/432 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV52360855; called by muse, mutect2, varscan2
- AFM | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56919771; called by muse, mutect2, varscan2
- ALB | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 82/247 reads (33%) | catalogued as COSV55738023, COSV99891995; called by muse, mutect2, varscan2
- ALDH2 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV55665068; called by muse, mutect2, varscan2
- ANK3 | c.2758G>A p.D920N (on ENST00000280772 / NM_001320874.2; = p.D54N on NM_001149.3) | Missense Mutation (SNP) | VAF 103/195 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1378776980, COSV55075016; called by muse, mutect2, varscan2
- ARG1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950091; called by muse, mutect2, varscan2
- ARR3 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.647); catalogued as rs776671312; called by muse, mutect2, varscan2
- ATP10B | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as rs1196903728; called by muse, mutect2, varscan2
- ATXN2L | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 108/391 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1266694959; called by muse, mutect2, varscan2
- BCOR | c.5194G>A p.E1732K (on ENST00000378444 / NM_001123385.2; = p.E1698K on NM_017745.6) | Missense Mutation (SNP) | VAF 197/565 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1437936868, COSV100653058, COSV60700979; called by muse, mutect2, varscan2
- BEND5 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65716996; called by muse, mutect2, varscan2
- BIN1 | c.925G>A p.E309K (on ENST00000316724 / NM_001320642.1; = p.E293K on NM_004305.4) | Missense Mutation (SNP) | VAF 183/617 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs374565677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 184/297 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs371865335; called by muse, mutect2, varscan2
- CABP5 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV53152190, COSV53154049; called by muse, mutect2
- CDC20 | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 103/297 reads (35%) | catalogued as COSV60523048; called by muse, mutect2, varscan2
- CDH9 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 151/439 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50252882; called by muse, mutect2, varscan2
- CEP135 | c.615-1G>A p.X205_splice | Splice Site (SNP) | VAF 107/286 reads (37%) | catalogued as COSV99954814; called by muse, mutect2, varscan2
- CHCHD4 | c.166C>T p.L56F (on ENST00000396914 / NM_001098502.2; = p.L69F on NM_144636.3) | Missense Mutation (SNP) | VAF 108/356 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55500153; called by muse, mutect2, varscan2
- CNTNAP2 | c.3700G>C p.D1234H | Missense Mutation (SNP) | VAF 443/685 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV62147976, COSV62163752; called by muse, mutect2, varscan2
- COL18A1 | c.5134G>A p.E1712K (on ENST00000359759 / NM_130444.3; = p.E1477K on NM_030582.4) | Missense Mutation (SNP) | VAF 174/559 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs771981397; called by muse, mutect2, varscan2
- COL4A3 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866466057; called by muse, mutect2, varscan2
- COL5A1 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65670291; called by muse, varscan2
- CPE | c.1401G>A p.W467* | Nonsense Mutation (SNP) | VAF 68/229 reads (30%) | catalogued as COSV68579309; called by muse, mutect2, varscan2
- CSMD3 | c.5062G>A p.G1688R (on ENST00000297405 / NM_001363185.1; = p.G1584R on NM_052900.3) | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99833994; called by muse, mutect2, varscan2
- CYP2C19 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64906775; called by mutect2, varscan2
- DCAF8L1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1195330470, COSV71595215; called by muse, mutect2, varscan2
- DCHS1 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 93/409 reads (23%) | catalogued as COSV55039100; called by muse, mutect2, varscan2
- DCLK3 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101373880; called by muse, mutect2, varscan2
- DGAT2L6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as rs772168164; called by muse, mutect2, varscan2
- DGAT2L6 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1226474577; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 55/502 reads (11%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2
- DNAH3 | c.10168G>A p.E3390K | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as COSV54505260, COSV99768584; called by muse, mutect2, varscan2
- DNAH5 | c.10229C>T p.T3410M | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs186180802; called by muse, mutect2, varscan2
- DPF1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs766988824, COSV55909649; called by muse, mutect2
- DSEL | c.1874A>G p.K625R | Missense Mutation (SNP) | VAF 119/349 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59490499, COSV59490917; called by muse, mutect2, varscan2
- ELOA2 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 173/545 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99797416; called by muse, mutect2, varscan2
- ENC1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 143/441 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187893; called by muse, mutect2, varscan2
- ERBB4 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53521698, COSV53532242; called by muse, mutect2, varscan2
- ERN1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV70500344; called by muse, mutect2, varscan2
- F13B | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV100803324; called by muse, mutect2, varscan2
- FAM153B | c.271C>T p.R91W (on ENST00000253490; = p.R14W on NM_001265615.1) | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.835); catalogued as rs759541571; called by muse, mutect2, varscan2
- FAM47A | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 163/508 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1301512208, COSV100649985, COSV60494608; called by muse, mutect2, varscan2
- FAT4 | c.4838C>T p.S1613L | Missense Mutation (SNP) | VAF 127/378 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs956160354, COSV67903155; called by muse, mutect2, varscan2
- GLT6D1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as COSV65628406; called by muse, mutect2, varscan2
- GPR141 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 266/562 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150971296; called by muse, mutect2, varscan2
- GRIK3 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 162/451 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as rs765921193, COSV66140078; called by muse, mutect2, varscan2
- GRIN2A | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58026228; called by muse, mutect2, varscan2
- GRIN2C | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751104229; called by muse, mutect2
- GRM3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 138/529 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1019385107, COSV64469797; called by muse, mutect2, varscan2
- HBZ | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 92/454 reads (20%) | catalogued as rs765709518, COSV99429418; called by muse, mutect2, varscan2
- HTR5A | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 442/632 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV55281828; called by muse, mutect2, varscan2
- IDI2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs61738901, COSV52987214; called by muse, mutect2, varscan2
- IGKV3-11 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 183/562 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs753381834; called by muse, mutect2, varscan2
- IGKV3D-11 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 168/500 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.075); catalogued as rs780339739; called by muse, mutect2, varscan2
- IGSF22 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 152/461 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs373701224; called by muse, mutect2, varscan2
- INPP5E | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 52/361 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs1398662716; called by muse, mutect2, varscan2
- IRF8 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as rs371942842; called by muse, mutect2, varscan2
- KCNQ2 | c.2165G>A p.S722N (on ENST00000359125 / NM_172107.4; = p.S694N on NM_004518.6) | Missense Mutation (SNP) | VAF 236/700 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as rs980574000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT2 | c.3353G>A p.R1118K | Missense Mutation (SNP) | VAF 143/606 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1455712118, COSV54112259, COSV54113036; called by muse, mutect2, varscan2
- KIF4B | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV70530360; called by muse, mutect2
- LONRF3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 188/497 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1408862999; called by muse, mutect2, varscan2
- LTN1 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs747264702; called by muse, mutect2, varscan2
- MAGEA12 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 151/464 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1556833391, COSV100757077; called by muse, mutect2, varscan2
- MAP7 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs543935729, COSV100643776, COSV63417547; called by muse, mutect2, varscan2
- MPP4 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 148/418 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs1292941345; called by muse, mutect2, varscan2
- MROH2B | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68181244; called by muse, mutect2, varscan2
- MUC17 | c.6337C>T p.P2113S | Missense Mutation (SNP) | VAF 167/565 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV60279960; called by muse, mutect2, varscan2
- MUSK | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); catalogued as COSV51883929; called by muse, mutect2, varscan2
- MYBPC2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1199891898; called by muse, mutect2, varscan2
- NALCN | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 145/407 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99218369; called by muse, mutect2, varscan2
- NEB | c.13615G>A p.D4539N | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1419422417; called by muse, mutect2, varscan2
- NEXMIF | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 173/506 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766391935, COSV50083099; called by muse, mutect2, varscan2
- NNT | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 137/373 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52924168; called by muse, mutect2, varscan2
- NR1H2 | c.1180_1203del p.Q395_L402del | In Frame Del (DEL) | VAF 115/441 reads (26%) | catalogued as rs1397096933; called by mutect2, varscan2
- OBSCN | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 238/450 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99484332; called by muse, mutect2
- OR14C36 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 219/438 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.139); catalogued as rs765451400; called by muse, mutect2, varscan2
- OR2A12 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 96/612 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as rs1411232603; called by muse, mutect2, varscan2
- OR4C46 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV60218496; called by muse, mutect2, varscan2
- OR6K6 | c.569G>T p.W190L (on ENST00000368144; = p.W166L on NM_001005184.1) | Missense Mutation (SNP) | VAF 333/644 reads (52%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.905); catalogued as COSV63743549; called by muse, mutect2, varscan2
- OR6Y1 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 118/506 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56928491, COSV56930150; called by muse, mutect2
- OR6Y1 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 118/508 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225548; called by muse, mutect2
- OR8B8 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 145/436 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.05); catalogued as rs867312545; called by muse, mutect2, varscan2
- OR8K5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 148/397 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57889769; called by muse, mutect2, varscan2
- OTOGL | c.4772C>T p.P1591L (on ENST00000547103; = p.P1582L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54015002; called by muse, mutect2
- PCLO | c.12768G>A p.M4256I | Missense Mutation (SNP) | VAF 230/496 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1362193454, COSV100433963, COSV61630371; called by muse, mutect2, varscan2
- PDZD2 | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 135/429 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as COSV56851190; called by muse, mutect2, varscan2
- PHLDB2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs796635791; called by muse, mutect2, varscan2
- PI4K2B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV53511263; called by muse, mutect2, varscan2
- PLCG2 | c.3248C>T p.P1083L | Missense Mutation (SNP) | VAF 134/394 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63867684; called by muse, mutect2, varscan2
- PLEKHG2 | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 166/500 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as rs867759713, COSV52685137, COSV99218078; called by muse, mutect2, varscan2
- PLG | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV51981310; called by muse, mutect2, varscan2
- PNPLA2 | c.1050C>T p.I350= | Splice Region (SNP) | VAF 113/319 reads (35%) | catalogued as rs1415556055; called by muse, mutect2, varscan2
- PRLR | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 123/367 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1264483297, COSV51495444; called by muse, mutect2, varscan2
- PROM2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 125/392 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs780674390; called by muse, mutect2, varscan2
- RASL11B | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453079895; called by muse, mutect2, varscan2
- REPS2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 167/461 reads (36%) | catalogued as COSV58187476; called by muse, mutect2, varscan2
- RFX6 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as rs780273514, COSV60587947; called by muse, mutect2, varscan2
- RPS6KA3 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 111/331 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101084231, COSV101084737; called by muse, mutect2, varscan2
- SCNN1G | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 131/368 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55600886; called by muse, mutect2, varscan2
- SCYL2 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1304282878; called by muse, mutect2, varscan2
- SELENOP | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs370888824; called by muse, mutect2, varscan2
- SEMA6C | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 193/428 reads (45%) | catalogued as rs376608666; called by muse, mutect2, varscan2
- SERPINC1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 200/406 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.106); catalogued as rs267598176; called by muse, mutect2, varscan2
- SHROOM3 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 114/357 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV99934442; called by muse, mutect2, varscan2
- SIM1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as rs540345980, COSV53490706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC14A1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs372299852; called by muse, mutect2, varscan2
- SLC22A16 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100397883; called by muse, mutect2, varscan2
- SLC26A7 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 117/352 reads (33%) | catalogued as rs200934477, COSV52592539, COSV99404314; called by muse, mutect2, varscan2
- SLU7 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 142/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145536528; called by muse, mutect2, varscan2
- SPACA1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV99389474; called by muse, mutect2, varscan2
- SPATA18 | c.518A>C p.Q173P | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54646252; called by muse, mutect2, varscan2
- SPO11 | c.1098G>A p.M366I | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV61995186; called by muse, mutect2, varscan2
- SPON1 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 145/401 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100115811; called by muse, mutect2, varscan2
- SPTB | c.6577G>A p.G2193R | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs779026292; called by muse, mutect2, varscan2
- SPTBN4 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 199/545 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs753597803, COSV58946028; called by muse, mutect2, varscan2
- STEAP3 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 163/547 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs1439761109, COSV61530317; called by muse, mutect2, varscan2
- STXBP2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 145/400 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55405031; called by muse, mutect2, varscan2
- SYK | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65326761; called by muse, mutect2, varscan2
- SYNM | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100018719; called by muse, mutect2, varscan2
- TBC1D21 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1236548170; called by muse, mutect2, varscan2
- TBC1D22A | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 144/451 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs187687977; called by muse, mutect2, varscan2
- TCF4 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 153/420 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100610426; called by muse, mutect2, varscan2
- TENM4 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs772165174; called by muse, mutect2, varscan2
- TESPA1 | c.1234G>A p.E412K (on ENST00000316577 / NM_001098815.3; = p.E274K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.38); catalogued as rs745329933, COSV100345214; called by muse, mutect2, varscan2
- TEX15 | c.7144C>T p.H2382Y (on ENST00000256246; = p.H2765Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 131/352 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99821714; called by muse, mutect2, varscan2
- THSD7A | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 208/441 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051817932, COSV70264321; called by muse, mutect2, varscan2
- THSD7B | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs866712360; called by muse, mutect2, varscan2
- TLR8 | c.314G>A p.G105E (on ENST00000218032 / NM_138636.5; = p.G123E on NM_016610.4) | Missense Mutation (SNP) | VAF 191/560 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54321348; called by muse, mutect2, varscan2
- TMPRSS9 | c.2776G>A p.E926K (on ENST00000648592; = p.E892K on NM_182973.2) | Missense Mutation (SNP) | VAF 173/489 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs1303427855; called by muse, mutect2, varscan2
- TRAV9-1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1318668728; called by muse, mutect2, varscan2
- TRIM16L | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 168/495 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.254); catalogued as rs868161348; called by muse, mutect2, varscan2
- TRPC7 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 142/429 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as rs753754845, COSV61462929; called by muse, mutect2, varscan2
- TTN | c.65129G>A p.R21710Q (on ENST00000591111; = p.R14286Q on NM_003319.4) | Missense Mutation (SNP) | VAF 109/312 reads (35%) | PolyPhen benign (0.015); catalogued as rs376046188, COSV60178349; called by muse, mutect2, varscan2
- TTN | c.15312G>A p.M5104I (on ENST00000591111; = p.M4177I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/451 reads (39%) | PolyPhen benign (0.003); catalogued as COSV100592109, COSV100601634; called by muse, mutect2, varscan2
- TUBGCP5 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 156/468 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs563107079; called by muse, mutect2, varscan2
- UGT1A9 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 127/404 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100693423, COSV60855101; called by muse, varscan2
- VAT1L | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 140/419 reads (33%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.777); catalogued as COSV56819745; called by muse, mutect2, varscan2
- VIPR2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 330/496 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs370731634; called by muse, mutect2, varscan2
- XIRP2 | c.2216G>A p.W739* (on ENST00000628543; = p.W914* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 128/382 reads (34%) | catalogued as COSV54694499; called by muse, mutect2, varscan2
- ZBTB7C | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 262/694 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs753250987, COSV59687700; called by muse, mutect2
- ZDHHC11 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs754095814, COSV52066996; called by muse, varscan2
- ZMAT4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52707472; called by muse, mutect2, varscan2
- ZNF211 | c.962C>T p.S321L (on ENST00000347302 / NM_198855.4; = p.S334L on NM_006385.5) | Missense Mutation (SNP) | VAF 154/430 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs753395520, COSV53742804; called by muse, mutect2, varscan2
- ZNF217 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 143/473 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1050089976; called by muse, mutect2, varscan2
- ZNF608 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 130/372 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1291706530; called by muse, mutect2, varscan2
- ZNF676 | c.1003C>T p.H335Y (on ENST00000650058; = p.H303Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 161/646 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68094953; called by muse, varscan2
- ZNF69 | c.131C>T p.S44F (on ENST00000429654 / NM_001364730.1; = p.S30F on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV60902998, COSV60903417; called by muse, mutect2, varscan2
- ZNF804A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 152/393 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs767783310, COSV56437143; called by muse, mutect2, varscan2
- ZSCAN21 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 153/690 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as rs1303232731, COSV52849187; called by muse, mutect2, varscan2
- ABCB7 | c.1558C>T p.R520C (on ENST00000373394 / NM_001271696.3; = p.R521C on NM_004299.6) | Missense Mutation (SNP) | VAF 114/373 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG1 | c.1451T>A p.F484Y | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAL | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRE1 | c.1061A>T p.N354I | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADGRV1 | c.4285A>T p.I1429F | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.5468G>A p.G1823E | Missense Mutation (SNP) | VAF 122/378 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AJM1 | c.1564G>C p.G522R | Missense Mutation (SNP) | VAF 184/411 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ALPK2 | c.3520C>T p.H1174Y | Missense Mutation (SNP) | VAF 141/377 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by mutect2, varscan2
- ARMC2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ASS1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ATP1A3 | c.772C>T p.R258W (on ENST00000545399 / NM_001256214.2; = p.R245W on NM_152296.5) | Missense Mutation (SNP) | VAF 132/397 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BECN2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 417/773 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- BEND5 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 116/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIN2 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 146/421 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIN2 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 145/422 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- BIRC5 | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- BMP15 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 73/799 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.157); called by muse, mutect2
- CAPN10 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CASP8 | c.367C>T p.L123F (on ENST00000432109 / NM_033355.3; = p.L155F on NM_001228.4) | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDH16 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 158/469 reads (34%) | called by muse, mutect2, varscan2
- CDH26 | c.1253T>A p.F418Y | Missense Mutation (SNP) | VAF 109/315 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLEC4E | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CR1 | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 300/568 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CRYL1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 95/321 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CST7 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 120/454 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DACH2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDRGK1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DHX40 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- DISP3 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 169/590 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DKC1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOK7 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 223/586 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPF3 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 201/446 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- E2F8 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- EFTUD2 | c.1046T>G p.F349C | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EIF2B2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 101/395 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ENAH | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 102/585 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ENAH | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 101/588 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ENPP4 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 64/708 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- EOLA2 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 147/463 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- EPHA7 | c.2964G>A p.M988I | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ETV1 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 246/560 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- F11 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM160A1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 153/483 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FBN2 | c.2450A>G p.N817S | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- FBXO40 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FFAR1 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 210/653 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.933); called by muse, mutect2
- FGL2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 106/501 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- FLOT2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 125/364 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- GBA3 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, varscan2
- GPRASP1 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 174/525 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRAMD4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 150/374 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- HACE1 | c.1118del p.L373* | Frame Shift Del (DEL) | VAF 62/199 reads (31%) | called by mutect2, pindel, varscan2
- HCN4 | c.3326C>T p.S1109L | Missense Mutation (SNP) | VAF 191/592 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPUL1 | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 123/320 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HOXC10 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 122/439 reads (28%) | called by muse, mutect2, varscan2
- HTR3C | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 88/295 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, varscan2
- HYDIN | c.2593G>A p.V865I | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHA1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 119/999 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- JPH4 | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- KCTD15 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 189/500 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- KRT2 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 144/399 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- LARS2 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAX1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 278/518 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDHC | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, varscan2
- LGSN | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 116/281 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC3B | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 92/333 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LY75 | c.3944G>A p.G1315E | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAP3K15 | c.3780+1G>A p.X1260_splice | Splice Site (SNP) | VAF 95/259 reads (37%) | called by muse, mutect2, varscan2
- MAP3K5 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MAP7D3 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MCTP1 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGAM2 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MINAR2 | c.165G>A p.Q55= | Splice Region (SNP) | VAF 83/228 reads (36%) | called by muse, mutect2, varscan2
- MIOS | c.2078T>C p.V693A | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MME | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- MOXD1 | c.265-6C>T | Splice Region (SNP) | VAF 46/271 reads (17%) | called by muse, mutect2, varscan2
- MROH2B | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MXRA5 | c.5887T>A p.Y1963N | Missense Mutation (SNP) | VAF 169/481 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- MYBBP1A | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MYO7A | c.5809C>T p.L1937F | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- NAB2 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEURL4 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 149/448 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEURL4 | c.3292C>T p.P1098S | Missense Mutation (SNP) | VAF 148/444 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NEXMIF | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 185/531 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NEXMIF | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- NIBAN1 | c.1375T>C p.S459P | Missense Mutation (SNP) | VAF 40/574 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NKX6-3 | c.710C>T p.P237L (on ENST00000518699 / NM_001364841.2; = p.P107L on NM_152568.3) | Missense Mutation (SNP) | VAF 188/494 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NOS1 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 128/448 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR10AC1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 108/808 reads (13%) | SIFT deleterious, low confidence (0.02); called by muse, varscan2
- OR10G3 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H2 | c.662C>T p.S221F (on ENST00000556246; = p.S232F on NM_001197287.1) | Missense Mutation (SNP) | VAF 119/413 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OR6K6 | c.881C>T p.S294L (on ENST00000368144; = p.S270L on NM_001005184.1) | Missense Mutation (SNP) | VAF 145/568 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OR8J2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- OXCT1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OXR1 | c.2492G>A p.G831E (on ENST00000442977 / NM_001198532.1; = p.G803E on NM_018002.3) | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.2314C>A p.Q772K | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.411); called by muse, mutect2
- PDZD2 | c.5118G>A p.M1706I | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEX11A | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 165/452 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PGLYRP4 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 235/450 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIWIL1 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PLEKHG2 | c.2528C>G p.P843R | Missense Mutation (SNP) | VAF 178/536 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PNPLA8 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 188/376 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR3D | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- POLR3F | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 161/466 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PPP3CB | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PRAMEF17 | c.664G>T p.G222* | Nonsense Mutation (SNP) | VAF 155/356 reads (44%) | called by muse, mutect2, varscan2
- PRKCQ | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 156/442 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTGDR | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RASGRF1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RASGRF1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RELN | c.7796C>T p.S2599F | Missense Mutation (SNP) | VAF 245/533 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFPL4AL1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 114/688 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, varscan2
- RHOB | c.78T>G p.S26R | Missense Mutation (SNP) | VAF 136/255 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- RIPOR2 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 56/689 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2
- RMND5A | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- RNF135 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SAP130 | c.734dup p.T246Nfs*67 | Frame Shift Ins (INS) | VAF 73/313 reads (23%) | called by mutect2, pindel, varscan2
- SLC12A6 | c.899C>T p.A300V (on ENST00000354181 / NM_001365088.1; = p.A249V on NM_005135.2) | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC34A1 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 36/534 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SLC35D1 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLK | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SMOC2 | c.808C>T p.P270S (on ENST00000356284 / NM_001166412.2; = p.P281S on NM_022138.3) | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SNCAIP | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 136/387 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNX25 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 131/420 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SNX8 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 182/418 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SPAG16 | c.1685C>A p.P562Q | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SSTR2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 144/461 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SSX5 | c.112G>A p.E38K (on ENST00000347757 / NM_175723.1; = p.E79K on NM_021015.4) | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- STAG2 | c.1836A>T p.L612F | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SUN5 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SYT3 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 195/540 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TAFA1 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 124/382 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D9B | c.2975G>A p.G992E (on ENST00000356834 / NM_198868.3; = p.G975E on NM_015043.4) | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEP1 | c.4583C>T p.A1528V | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TIE1 | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM63B | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TPTE | c.323T>C p.L108P (on ENST00000618007 / NM_199261.4; = p.L90P on NM_199259.4) | Missense Mutation (SNP) | VAF 32/636 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TRANK1 | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 125/350 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRIM40 | c.547G>A p.E183K (on ENST00000376724; = p.E154K on NM_138700.4) | Missense Mutation (SNP) | VAF 625/920 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTBK1 | c.3824G>A p.G1275D | Missense Mutation (SNP) | VAF 132/565 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- TTN | c.22918G>T p.G7640* (on ENST00000591111; = p.G6713* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 110/432 reads (25%) | called by muse, mutect2, varscan2
- UGT2A2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 132/410 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USHBP1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 165/465 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- USP12 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP24 | c.7858C>T p.P2620S | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- USP26 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP46 | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 118/338 reads (35%) | called by muse, mutect2, varscan2
- UTP14A | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 133/448 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- VWA3B | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WDR17 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPO7 | c.3035A>T p.N1012I | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- XRN1 | c.3449G>A p.G1150E | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZFYVE1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 148/373 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ZNF45 | c.785A>T p.H262L | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF597 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 110/394 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACE2 | c.141T>C p.S47= | Silent (SNP) | VAF 126/341 reads (37%) | called by muse, mutect2, varscan2
- ACTRT1 | c.501C>T p.P167= | Silent (SNP) | VAF 164/494 reads (33%) | called by muse, mutect2, varscan2
- ADGRV1 | c.2886C>T p.S962= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as rs933538755, COSV67995127; called by muse, mutect2, varscan2
- ADGRV1 | c.12879A>C p.G4293= | Silent (SNP) | VAF 87/282 reads (31%) | called by muse, mutect2, varscan2
- ADSS1 | c.1125C>T p.V375= | Silent (SNP) | VAF 124/398 reads (31%) | catalogued as rs144889835; called by muse, mutect2
- AHDC1 | c.3687C>T p.S1229= | Silent (SNP) | VAF 172/439 reads (39%) | called by muse, mutect2, varscan2
- AJM1 | c.1563G>A p.E521= | Silent (SNP) | VAF 183/410 reads (45%) | called by muse, mutect2, varscan2
- ALG13 | c.1449T>G p.S483= | Silent (SNP) | VAF 39/306 reads (13%) | called by muse, mutect2, varscan2
- AMOTL1 | c.684C>T p.S228= | Silent (SNP) | VAF 192/510 reads (38%) | called by muse, mutect2, varscan2
- ANK1 | c.306C>T p.A102= | Silent (SNP) | VAF 72/329 reads (22%) | catalogued as COSV99223647; called by muse, mutect2, varscan2
- APOB | c.9957T>C p.D3319= | Silent (SNP) | VAF 136/249 reads (55%) | catalogued as rs1484004752; called by muse, mutect2, varscan2
- APOBEC3G | c.453C>T p.I151= | Silent (SNP) | VAF 119/290 reads (41%) | called by muse, mutect2, varscan2
- ARID3B | c.438C>T p.L146= | Silent (SNP) | VAF 64/617 reads (10%) | catalogued as rs148000812; called by muse, mutect2, varscan2
- ARL6IP1 | c.573A>T p.I191= | Silent (SNP) | VAF 112/290 reads (39%) | called by muse, mutect2, varscan2
- ASDURF | c.237G>A p.L79= | Silent (SNP) | VAF 75/235 reads (32%) | called by muse, mutect2, varscan2
- ATP4A | c.2385C>T p.I795= | Silent (SNP) | VAF 124/386 reads (32%) | called by muse, mutect2, varscan2
- ATXN2L | c.3201G>A p.Q1067= | Silent (SNP) | VAF 111/393 reads (28%) | called by muse, mutect2, varscan2
- BICD2 | c.1995G>A p.V665= | Silent (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- BTK | c.594G>A p.L198= | Silent (SNP) | VAF 114/293 reads (39%) | called by muse, mutect2, varscan2
- C14orf93 | c.1491C>T p.F497= | Silent (SNP) | VAF 166/406 reads (41%) | called by muse, mutect2, varscan2
- C7 | c.1152C>T p.F384= | Silent (SNP) | VAF 110/359 reads (31%) | called by muse, mutect2, varscan2
- CCDC33 | c.1305C>T p.Y435= | Silent (SNP) | VAF 73/227 reads (32%) | called by muse, mutect2, varscan2
- CD163 | c.3462G>A p.G1154= | Silent (SNP) | VAF 56/204 reads (27%) | catalogued as COSV100775785; called by muse, mutect2, varscan2
- CHCHD4 | c.165C>T p.C55= (on ENST00000396914 / NM_001098502.2; = p.C68= on NM_144636.3) | Silent (SNP) | VAF 108/347 reads (31%) | called by muse, mutect2, varscan2
- CLEC16A | c.1161G>T p.V387= | Silent (SNP) | VAF 141/413 reads (34%) | called by muse, mutect2, varscan2
- COL11A1 | c.3363C>T p.S1121= | Silent (SNP) | VAF 124/393 reads (32%) | called by muse, mutect2, varscan2
- COL18A1 | c.5133G>A p.T1711= (on ENST00000359759 / NM_130444.3; = p.T1476= on NM_030582.4) | Silent (SNP) | VAF 158/516 reads (31%) | catalogued as rs761670508; called by muse, varscan2
- COL5A1 | c.4707G>A p.P1569= | Silent (SNP) | VAF 122/246 reads (50%) | catalogued as rs370009851, COSV65668232; called by muse, mutect2, varscan2
- COL6A3 | c.6639C>T p.G2213= | Silent (SNP) | VAF 102/316 reads (32%) | catalogued as rs765837100, COSV55081842; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- COMMD10 | c.546G>A p.K182= | Silent (SNP) | VAF 72/229 reads (31%) | called by muse, mutect2, varscan2
- CPNE9 | c.702C>T p.F234= | Silent (SNP) | VAF 95/307 reads (31%) | catalogued as COSV56067999; called by muse, mutect2, varscan2
- CPSF1 | c.612C>T p.I204= | Silent (SNP) | VAF 149/435 reads (34%) | catalogued as COSV100574673; called by muse, mutect2, varscan2
- CROCC2 | c.3606G>A p.K1202= | Silent (SNP) | VAF 208/594 reads (35%) | called by muse, mutect2, varscan2
- DNAH2 | c.5946C>T p.S1982= | Silent (SNP) | VAF 161/438 reads (37%) | called by muse, mutect2, varscan2
- DNER | c.495C>T p.I165= | Silent (SNP) | VAF 150/412 reads (36%) | catalogued as COSV59161236; called by muse, mutect2, varscan2
- DNMBP | c.1152C>T p.P384= | Silent (SNP) | VAF 159/330 reads (48%) | called by muse, mutect2, varscan2
- DOT1L | c.2253C>T p.T751= | Silent (SNP) | VAF 189/531 reads (36%) | called by muse, mutect2, varscan2
- DPF1 | c.1098C>T p.L366= | Silent (SNP) | VAF 108/370 reads (29%) | catalogued as rs892376384; called by muse, mutect2
- DSCAM | c.5841G>A p.P1947= | Silent (SNP) | VAF 185/483 reads (38%) | catalogued as rs754261783, COSV68021904; called by muse, mutect2, varscan2
- DSCAM | c.285C>T p.I95= | Silent (SNP) | VAF 130/412 reads (32%) | catalogued as rs541570716; called by muse, mutect2, varscan2
- DYNC2I1 | c.66C>T p.L22= | Silent (SNP) | VAF 69/495 reads (14%) | catalogued as rs1472138603; called by muse, mutect2, varscan2
- EFTUD2 | c.1047C>T p.F349= | Silent (SNP) | VAF 97/318 reads (31%) | catalogued as COSV68184857; called by muse, mutect2, varscan2
- ELF4 | c.1359C>T p.F453= | Silent (SNP) | VAF 195/569 reads (34%) | called by muse, mutect2, varscan2
- ELMOD1 | c.615G>A p.P205= | Silent (SNP) | VAF 124/288 reads (43%) | catalogued as rs772952763; called by muse, mutect2, varscan2
- ENOX1 | c.1098G>A p.S366= | Silent (SNP) | VAF 110/340 reads (32%) | catalogued as rs770349357, COSV54895942; called by muse, mutect2, varscan2
- EOLA2 | c.408G>A p.R136= | Silent (SNP) | VAF 146/462 reads (32%) | catalogued as rs367632870; called by muse, mutect2, varscan2
- ERICH3 | c.1674G>A p.V558= | Silent (SNP) | VAF 155/474 reads (33%) | catalogued as COSV58617544; called by muse, mutect2, varscan2
- EZHIP | c.1041C>T p.S347= | Silent (SNP) | VAF 179/499 reads (36%) | called by muse, mutect2, varscan2
- F11 | c.1560G>A p.G520= | Silent (SNP) | VAF 72/242 reads (30%) | called by muse, mutect2, varscan2
- FAM110D | c.399A>C p.S133= | Silent (SNP) | VAF 420/838 reads (50%) | called by muse, mutect2, varscan2
- FAM135B | c.2046C>T p.I682= | Silent (SNP) | VAF 162/472 reads (34%) | called by muse, mutect2, varscan2
- FAM160A1 | c.1026C>T p.F342= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV70706059; called by muse, mutect2, varscan2
- FAM160A1 | c.2049C>T p.P683= | Silent (SNP) | VAF 151/481 reads (31%) | catalogued as rs1416244963; called by muse, mutect2, varscan2
- FAM83F | c.819C>T p.L273= | Silent (SNP) | VAF 108/345 reads (31%) | called by muse, mutect2, varscan2
- FAM83H | c.2040C>T p.S680= | Silent (SNP) | VAF 243/584 reads (42%) | called by muse, mutect2, varscan2
- FBXO40 | c.204C>T p.S68= | Silent (SNP) | VAF 137/383 reads (36%) | catalogued as rs201758749; called by muse, mutect2, varscan2
- FCHO1 | c.2472C>T p.S824= | Silent (SNP) | VAF 102/312 reads (33%) | catalogued as rs370950809, COSV99406189; called by muse, mutect2, varscan2
- FOLR1 | c.588C>T p.S196= | Silent (SNP) | VAF 128/406 reads (32%) | catalogued as rs755278391, COSV56616836; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GABRB2 | c.1452G>A p.V484= (on ENST00000274547; = p.V446= on NM_000813.3) | Silent (SNP) | VAF 170/437 reads (39%) | called by muse, mutect2, varscan2
- GDPD1 | c.426C>T p.A142= | Silent (SNP) | VAF 106/348 reads (30%) | catalogued as rs1226821183; called by muse, mutect2, varscan2
- GFY | c.174C>T p.N58= | Silent (SNP) | VAF 118/422 reads (28%) | called by muse, mutect2, varscan2
- GIMAP8 | c.1281G>A p.G427= | Silent (SNP) | VAF 345/513 reads (67%) | catalogued as rs867599282, COSV56229782; called by muse, mutect2, varscan2
- GMFB | c.354C>T p.T118= | Silent (SNP) | VAF 79/287 reads (28%) | called by muse, mutect2, varscan2
- GRIN2B | c.2517A>G p.E839= | Silent (SNP) | VAF 102/320 reads (32%) | called by muse, mutect2, varscan2
- HCN1 | c.789C>T p.L263= | Silent (SNP) | VAF 142/434 reads (33%) | catalogued as rs1359320329, COSV100298128; called by muse, mutect2, varscan2
- HM13 | c.579C>T p.S193= | Silent (SNP) | VAF 111/351 reads (32%) | catalogued as rs977034336, COSV59438545; called by muse, mutect2, varscan2
- HNRNPCL1 | c.750G>A p.E250= | Silent (SNP) | VAF 233/924 reads (25%) | called by muse, mutect2, varscan2
- HSPG2 | c.6679C>T p.L2227= | Silent (SNP) | VAF 149/508 reads (29%) | called by muse, mutect2, varscan2
- HTR3C | c.12G>A p.G4= | Silent (SNP) | VAF 96/321 reads (30%) | called by muse, mutect2, varscan2
- HYDIN | c.8013G>A p.E2671= | Silent (SNP) | VAF 73/260 reads (28%) | catalogued as rs774742133; called by muse, mutect2, varscan2
- IER5 | c.453G>A p.A151= | Silent (SNP) | VAF 373/676 reads (55%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.507G>A p.G169= | Silent (SNP) | VAF 149/506 reads (29%) | catalogued as rs267604935; called by muse, varscan2
- IL12RB1 | c.150G>A p.L50= | Silent (SNP) | VAF 85/292 reads (29%) | called by muse, mutect2, varscan2
- ITGB4 | c.2652G>A p.V884= | Silent (SNP) | VAF 100/356 reads (28%) | called by muse, mutect2, varscan2
- JAGN1 | c.408C>T p.Y136= | Silent (SNP) | VAF 141/424 reads (33%) | catalogued as COSV57061529; called by muse, mutect2, varscan2
- JPH4 | c.1164C>T p.A388= | Silent (SNP) | VAF 98/281 reads (35%) | called by muse, mutect2, varscan2
- KCTD15 | c.612C>T p.S204= | Silent (SNP) | VAF 191/501 reads (38%) | catalogued as rs937645040; called by muse, mutect2, varscan2
- KIAA0319 | c.1197C>G p.S399= | Silent (SNP) | VAF 221/308 reads (72%) | called by muse, mutect2, varscan2
- KIAA1109 | c.1140C>T p.I380= | Silent (SNP) | VAF 105/305 reads (34%) | called by muse, mutect2, varscan2
- KIF6 | c.1185G>A p.L395= | Silent (SNP) | VAF 218/311 reads (70%) | called by muse, mutect2, varscan2
- KL | c.897C>T p.S299= | Silent (SNP) | VAF 144/362 reads (40%) | called by muse, mutect2, varscan2
- LEFTY2 | c.174G>A p.R58= | Silent (SNP) | VAF 360/680 reads (53%) | called by muse, mutect2, varscan2
- LHFPL1 | c.33C>T p.L11= | Silent (SNP) | VAF 152/464 reads (33%) | catalogued as COSV64333735; called by muse, mutect2, varscan2
- LOXL4 | c.2229C>T p.L743= | Silent (SNP) | VAF 118/213 reads (55%) | called by muse, mutect2, varscan2
- LRFN1 | c.643C>T p.L215= | Silent (SNP) | VAF 160/468 reads (34%) | called by muse, mutect2, varscan2
- LRP1 | c.11682C>T p.F3894= | Silent (SNP) | VAF 158/492 reads (32%) | catalogued as rs746880837; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.709C>T p.L237= | Silent (SNP) | VAF 66/1014 reads (7%) | called by muse, mutect2
- MAGEA3 | c.48T>G p.L16= | Silent (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- MAGEB10 | c.447C>T p.F149= | Silent (SNP) | VAF 186/529 reads (35%) | called by muse, mutect2, varscan2
- MFN2 | c.399C>T p.F133= | Silent (SNP) | VAF 172/570 reads (30%) | catalogued as rs749714655; called by muse, mutect2, varscan2
- MMP15 | c.645C>T p.T215= | Silent (SNP) | VAF 146/438 reads (33%) | catalogued as rs760670479; called by muse, mutect2, varscan2
- MRGPRE | c.938G>A p.*313= | Silent (SNP) | VAF 109/351 reads (31%) | catalogued as rs1238567136; called by muse, mutect2, varscan2
- MTMR11 | c.381C>T p.I127= (on ENST00000439741 / NM_001145862.2; = p.I55= on NM_181873.3) | Silent (SNP) | VAF 128/534 reads (24%) | catalogued as rs782104828; called by muse, mutect2, varscan2
- MYO7A | c.2034C>T p.F678= | Silent (SNP) | VAF 124/403 reads (31%) | catalogued as rs782519043, COSV101289094; called by muse, mutect2, varscan2
- MYO7A | c.5808C>T p.L1936= | Silent (SNP) | VAF 105/326 reads (32%) | called by muse, mutect2, varscan2
- NALCN | c.3495G>A p.T1165= | Silent (SNP) | VAF 100/274 reads (36%) | catalogued as rs757748955; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCOA5 | c.315C>T p.P105= | Silent (SNP) | VAF 100/352 reads (28%) | catalogued as rs1186483039, COSV99275453; called by muse, mutect2, varscan2
- NLRP12 | c.672C>T p.S224= | Silent (SNP) | VAF 171/489 reads (35%) | called by muse, mutect2, varscan2
- NNT | c.1800C>T p.L600= | Silent (SNP) | VAF 135/376 reads (36%) | catalogued as COSV52927003; called by muse, mutect2, varscan2
- OCSTAMP | c.132C>T p.S44= | Silent (SNP) | VAF 134/417 reads (32%) | called by muse, mutect2, varscan2
- OPN5 | c.543C>T p.T181= | Silent (SNP) | VAF 460/686 reads (67%) | called by muse, mutect2, varscan2
- OR4C5 | c.594C>T p.F198= | Silent (SNP) | VAF 98/325 reads (30%) | called by muse, mutect2, varscan2
- OR5B17 | c.654C>T p.F218= | Silent (SNP) | VAF 67/268 reads (25%) | catalogued as COSV62159817; called by muse, mutect2, varscan2
- OR6B3 | c.9G>A p.G3= | Silent (SNP) | VAF 101/264 reads (38%) | catalogued as COSV100097735; called by muse, mutect2, varscan2
- P3H2 | c.1398C>T p.L466= | Silent (SNP) | VAF 128/345 reads (37%) | called by muse, mutect2, varscan2
- PAPPA | c.2916C>T p.S972= | Silent (SNP) | VAF 113/258 reads (44%) | called by muse, mutect2, varscan2
- PCDHA11 | c.2385C>A p.P795= | Silent (SNP) | VAF 103/393 reads (26%) | catalogued as COSV100248401; called by muse, mutect2, varscan2
- PCSK9 | c.771G>A p.G257= | Silent (SNP) | VAF 154/486 reads (32%) | catalogued as COSV56164210; called by muse, mutect2, varscan2
- PI4KB | c.627C>T p.S209= (on ENST00000368873 / NM_001369623.1; = p.S221= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 145/611 reads (24%) | catalogued as COSV55017532; called by muse, mutect2, varscan2
- PIGN | c.1657C>T p.L553= | Silent (SNP) | VAF 97/307 reads (32%) | catalogued as COSV62952242; called by muse, mutect2, varscan2
- PKMYT1 | c.1035G>A p.K345= | Silent (SNP) | VAF 204/591 reads (35%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1692C>T p.A564= | Silent (SNP) | VAF 197/403 reads (49%) | called by muse, mutect2, varscan2
- POC1A | c.789G>T p.L263= | Silent (SNP) | VAF 125/381 reads (33%) | called by muse, mutect2, varscan2
- PPP2R5C | c.427A>C p.R143= | Silent (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- PRDM15 | c.2046C>T p.D682= | Silent (SNP) | VAF 100/393 reads (25%) | catalogued as rs146139958; called by muse, mutect2, varscan2
- PRDM16 | c.516C>T p.I172= | Silent (SNP) | VAF 103/446 reads (23%) | catalogued as rs865858938, COSV54608725; called by muse, mutect2, varscan2
- PRMT3 | c.1287C>A p.I429= | Silent (SNP) | VAF 70/220 reads (32%) | catalogued as COSV58175156; called by mutect2, varscan2
- PRPF8 | c.456C>T p.R152= | Silent (SNP) | VAF 112/353 reads (32%) | called by muse, varscan2
- PRR23A | c.133C>T p.L45= | Silent (SNP) | VAF 174/568 reads (31%) | catalogued as rs1359077173; called by muse, mutect2, varscan2
- PTPRT | c.2889G>A p.P963= | Silent (SNP) | VAF 60/164 reads (37%) | catalogued as rs767426417, COSV61960161; called by muse, mutect2, varscan2
- PXDNL | c.2097C>T p.S699= | Silent (SNP) | VAF 105/343 reads (31%) | called by muse, mutect2, varscan2
- RASEF | c.1671C>T p.F557= | Silent (SNP) | VAF 146/330 reads (44%) | catalogued as rs1480685109, COSV64586784; called by muse, mutect2, varscan2
- RASGRF2 | c.1227G>A p.R409= | Silent (SNP) | VAF 89/282 reads (32%) | catalogued as COSV99429714; called by muse, mutect2, varscan2
- RIPPLY3 | c.546G>A p.R182= | Silent (SNP) | VAF 129/332 reads (39%) | called by muse, mutect2, varscan2
- SCYL2 | c.1998G>A p.E666= | Silent (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2, varscan2
- SELL | c.561C>T p.I187= (on ENST00000650983; = p.I174= on NM_000655.5) | Silent (SNP) | VAF 90/380 reads (24%) | catalogued as rs749524262, COSV52554133; called by muse, mutect2, varscan2
- SERPINA10 | c.537C>T p.F179= | Silent (SNP) | VAF 133/482 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.636C>T p.T212= | Silent (SNP) | VAF 182/557 reads (33%) | catalogued as rs776394512, COSV55780585, COSV99707934; called by muse, mutect2, varscan2
- SLC10A3 | c.588C>T p.L196= | Silent (SNP) | VAF 185/566 reads (33%) | called by muse, mutect2, varscan2
- SLC12A9 | c.243C>T p.F81= | Silent (SNP) | VAF 255/540 reads (47%) | catalogued as rs1192839306; called by muse, mutect2, varscan2
- SLC45A3 | c.885C>T p.F295= | Silent (SNP) | VAF 148/579 reads (26%) | catalogued as rs202134707, COSV65654805; called by muse, mutect2, varscan2
- SLC6A13 | c.1248G>A p.R416= | Silent (SNP) | VAF 110/347 reads (32%) | called by muse, mutect2, varscan2
- SLC8A3 | c.2382C>T p.F794= (on ENST00000381269 / NM_183002.3; = p.F792= on NM_033262.4) | Silent (SNP) | VAF 94/435 reads (22%) | catalogued as rs368263429; called by muse, mutect2, varscan2
- SMS | c.993G>A p.Q331= | Silent (SNP) | VAF 175/476 reads (37%) | called by muse, mutect2, varscan2
- SPATA20 | c.1233C>T p.L411= (on ENST00000356488 / NM_001258372.1; = p.L427= on NM_022827.4) | Silent (SNP) | VAF 156/421 reads (37%) | catalogued as rs146293806; called by muse, mutect2, varscan2
- SREK1 | c.901C>A p.R301= | Silent (SNP) | VAF 62/447 reads (14%) | called by muse, mutect2, varscan2
- STAMBP | c.960C>T p.F320= | Silent (SNP) | VAF 130/414 reads (31%) | catalogued as COSV59896746; called by muse, mutect2, varscan2
- TCF21 | c.135G>A p.E45= | Silent (SNP) | VAF 135/319 reads (42%) | catalogued as COSV52819105; called by muse, mutect2, varscan2
- THNSL2 | c.381C>T p.F127= | Silent (SNP) | VAF 108/321 reads (34%) | catalogued as rs979373211, COSV59084335; called by muse, mutect2, varscan2
- TRBV2 | c.330C>T p.F110= | Silent (SNP) | VAF 233/357 reads (65%) | called by muse, mutect2, varscan2
- TRIOBP | c.1917C>T p.P639= | Silent (SNP) | VAF 218/682 reads (32%) | catalogued as rs769783327; called by muse, varscan2
- TTN | c.22440C>T p.F7480= (on ENST00000591111; = p.F6553= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/324 reads (31%) | catalogued as rs754815317, COSV59933248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3456G>A p.R1152= | Silent (SNP) | VAF 79/306 reads (26%) | catalogued as COSV54439421; called by muse, mutect2, varscan2
- UNC79 | c.1935G>A p.R645= (on ENST00000393151 / NM_001346218.2; = p.R468= on NM_020818.5) | Silent (SNP) | VAF 55/248 reads (22%) | called by muse, mutect2, varscan2
- USP27X | c.888G>A p.Q296= | Silent (SNP) | VAF 140/425 reads (33%) | called by muse, mutect2, varscan2
- VIT | c.402C>T p.I134= | Silent (SNP) | VAF 93/169 reads (55%) | catalogued as rs771589743, COSV64898458; called by muse, mutect2, varscan2
- WDFY4 | c.3118C>T p.L1040= | Silent (SNP) | VAF 106/220 reads (48%) | catalogued as rs1277951615; called by muse, mutect2, varscan2
- WDHD1 | c.684C>T p.F228= | Silent (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- ZFAT | c.1575C>T p.L525= | Silent (SNP) | VAF 167/488 reads (34%) | catalogued as rs747583926; called by muse, mutect2, varscan2
- ZFHX3 | c.10209C>T p.V3403= | Silent (SNP) | VAF 165/449 reads (37%) | catalogued as rs779040466, COSV51709197; called by muse, mutect2, varscan2
- ZFYVE28 | c.264C>T p.F88= | Silent (SNP) | VAF 172/506 reads (34%) | catalogued as COSV99342344; called by muse, mutect2, varscan2
- ZMYM3 | c.1407C>T p.L469= | Silent (SNP) | VAF 192/577 reads (33%) | catalogued as rs776907930; called by muse, mutect2, varscan2
- ZNF181 | c.1317G>A p.R439= | Silent (SNP) | VAF 22/400 reads (6%) | called by muse, mutect2
- ZNF385A | c.945C>T p.F315= (on ENST00000338010 / NM_001130967.3; = p.F295= on NM_015481.3) | Silent (SNP) | VAF 101/316 reads (32%) | called by muse, mutect2, varscan2
- ZNF420 | c.1311C>T p.H437= | Silent (SNP) | VAF 98/459 reads (21%) | called by muse, mutect2, varscan2
- ZNF493 | c.270C>T p.A90= | Silent (SNP) | VAF 85/299 reads (28%) | catalogued as COSV100828729; called by muse, mutect2, varscan2
- CD72 | c.262+90C>T | Intron (SNP) | VAF 179/304 reads (59%) | called by muse, mutect2, varscan2
- DCHS2 | n.8268G>A | RNA (SNP) | VAF 141/383 reads (37%) | catalogued as rs866887982, COSV61774024, COSV61781922; called by muse, mutect2, varscan2
- DEPDC5 | c.1445+16C>T | Intron (SNP) | VAF 147/474 reads (31%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20826C>T | Intron (SNP) | VAF 473/765 reads (62%) | catalogued as COSV100123892; called by muse, mutect2, varscan2
- EIF4G3 | c.2085+877C>T | Intron (SNP) | VAF 166/418 reads (40%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-12464C>T | Intron (SNP) | VAF 82/271 reads (30%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+31238C>T | Intron (SNP) | VAF 152/419 reads (36%) | catalogued as rs1188829693; called by muse, mutect2, varscan2
- KIF16B | c.3498+3441G>A | Intron (SNP) | VAF 72/189 reads (38%) | catalogued as COSV61705923; called by muse, mutect2, varscan2
- MCTS1 | c.12-543G>A | Intron (SNP) | VAF 140/444 reads (32%) | catalogued as COSV64892377; called by muse, mutect2, varscan2
- NRXN2 | c.3403+5424C>A | Intron (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- PFKP | c.265-407C>T | Intron (SNP) | VAF 141/414 reads (34%) | called by muse, mutect2, varscan2
- SDR16C5 | c.836+1592C>T | Intron (SNP) | VAF 92/279 reads (33%) | catalogued as rs1481685361, COSV58125595; called by muse, mutect2, varscan2
- TBC1D8B | c.1838-777C>T | Intron (SNP) | VAF 64/220 reads (29%) | catalogued as rs764124642; called by muse, mutect2
- TRPM3 | c.1816-881G>A | Intron (SNP) | VAF 65/164 reads (40%) | called by muse, mutect2, varscan2
- TVP23A | c.*2148G>A | 3'UTR (SNP) | VAF 106/305 reads (35%) | called by muse, mutect2, varscan2
- USH1C | c.1284+1146C>T | Intron (SNP) | VAF 118/331 reads (36%) | called by muse, mutect2, varscan2
